Gene-level copy-number profile of tumor specimen TCGA-ER-A19G-06A from TCGA case TCGA-ER-A19G, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 61.7 years (22,528 days).
Specimen TCGA-ER-A19G-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.4dfbb37d-2fa0-413f-b660-1a0b454881f7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ER-A19G-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9974f4ac-5fa5-4ecb-9035-069c40cccd83

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 54; copy number 1: 491; copy number 2: 6,095; copy number 3: 29,926; copy number 4: 15,769; copy number 5: 3,769; copy number 6: 3,246; copy number 7: 458; copy number 10: 6; copy number 12: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ER-A19G-06A-11D-A194-01): tumor purity 0.64, ploidy 3.53, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:274,190–689,668, 1 gene (within-gene range 0–3): DIP2C.
- chr10:430,239–441,170, 2 genes: RN7SL754P, AL669841.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 469 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:19,338,775–19,629,821, 5 genes, copy number 10 (within-gene range 6–10): CAPZB, RN7SL277P, MICOS10, RNU4-28P, AL031727.2.
- chr1:19,608,114–19,608,568, 1 gene, copy number 10: AL031727.1.
- chr5:58,198–12,574,637, 244 genes, copy number 7 (broad region; genes not listed).
- chr5:24,881,943–39,721,513, 214 genes, copy number 7 (broad region; genes not listed).
- chr7:38,256,337–38,276,318, 5 genes, copy number 12: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1.

Autosomal genes at a single copy (total copy number 1): 491. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
